Somatic mutation profile of tumor specimen C3N-00438-02 (aliquot CPT0379430007) from CPTAC case C3N-00438, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 67.3 years (24,576 days).
Specimen C3N-00438-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0cc762e-086f-4cea-b62c-62159bc01e10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00438-31 (Blood Derived Normal), aliquot CPT0379460002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fad18f4-2a79-4f5c-ab21-c1cf72f77338

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Splice Site 2, 5'UTR 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSPG4 | c.4577C>T p.A1526V | Missense Mutation (SNP) | VAF 29/373 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as rs1438423780; called by muse, mutect2
- DST | c.20509C>T p.R6837C (on ENST00000361203 / NM_001374722.1; = p.R4534C on NM_015548.5) | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758097621; called by muse, varscan2
- FADS3 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as rs770308115; called by muse, mutect2
- KCTD13 | c.125A>T p.Y42F | Missense Mutation (SNP) | VAF 24/419 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs1172094955; called by muse, mutect2
- RELN | c.10025C>T p.T3342M | Missense Mutation (SNP) | VAF 181/317 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs201703640, COSV100632026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPI1 | c.32A>G p.H11R | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1555131376; called by muse, mutect2
- ABCA10 | c.2066T>C p.V689A | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CBWD6 | c.952-5_957del p.X318_splice | Splice Site (DEL) | VAF 46/176 reads (26%) | called by mutect2, varscan2
- CRYL1 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.262); called by muse, varscan2
- DYNC1H1 | c.12416T>A p.L4139H | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FOS | c.636C>A p.F212L | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.3); called by muse, mutect2
- ILF3 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- LUM | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NDNF | c.313+1G>A p.X105_splice | Splice Site (SNP) | VAF 52/114 reads (46%) | called by muse, mutect2
- PLD5 | c.571G>C p.A191P (on ENST00000442594; = p.A129P on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM2 | c.2045T>A p.V682D (on ENST00000518659 / NM_001122679.2; = p.V450D on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2
- TNS3 | c.3930C>G p.A1310= | Splice Region (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2
- CECR2 | c.3414G>T p.P1138= (on ENST00000342247 / NM_001290047.2; = p.P954= on NM_001290046.1) | Silent (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- CLP1 | c.165C>T p.F55= | Silent (SNP) | VAF 22/376 reads (6%) | called by muse, mutect2
- GRIK4 | c.75G>A p.L25= | Silent (SNP) | VAF 77/219 reads (35%) | called by muse, mutect2, varscan2
- MAGEL2 | c.342T>C p.P114= | Silent (SNP) | VAF 16/264 reads (6%) | called by muse, mutect2
- MOCS3 | c.630C>T p.G210= | Silent (SNP) | VAF 111/344 reads (32%) | called by muse, mutect2, varscan2
- IDO2 | c.-58A>G | 5'UTR (SNP) | VAF 17/224 reads (8%) | called by muse, mutect2
- SCPEP1 | c.-12G>A | 5'UTR (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- ZEB2 | chr2:144520276 del CGCCCTGAGCGTGAGCATCATGTGAAAAC | 5'Flank (DEL) | VAF 66/198 reads (33%) | called by mutect2, pindel
